Somatic mutation profile of tumor specimen TCGA-CV-7437-01A (aliquot TCGA-CV-7437-01A-21D-2129-08) from TCGA case TCGA-CV-7437, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 77.3 years (28,221 days).
Specimen TCGA-CV-7437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c168c28-120f-4699-b49e-ae6cc2ab09a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7437-10A (Blood Derived Normal), aliquot TCGA-CV-7437-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caf3e452-1991-4def-8526-b6b9ac457786

The open-access MAF lists 135 somatic variants for this specimen: 100 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 34, Nonsense Mutation 14, Frame Shift Del 4, Splice Site 3, In Frame Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67960494; called by muse, mutect2, varscan2
- ABCG8 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as COSV99700328; called by muse, mutect2, varscan2
- AC008676.3 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100400414, COSV100400518; called by muse, mutect2, varscan2
- AKAP6 | c.6484G>A p.G2162S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99804774; called by muse, mutect2, varscan2
- ATF7 | c.1076G>T p.R359L (on ENST00000548446 / NM_001366555.2; = p.R348L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129819, COSV60644725; called by muse, mutect2, varscan2
- ATPSCKMT | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 65/190 reads (34%) | catalogued as rs763657110, COSV99725999; called by muse, mutect2, varscan2
- B3GNT6 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 81/121 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs977120737, COSV100845813; called by muse, mutect2, varscan2
- BARD1 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV99639996; called by muse, mutect2
- BAZ2B | c.5320G>A p.E1774K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs1559044413, COSV58599395; called by muse, mutect2, varscan2
- BPIFB4 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100971672; called by muse, mutect2, varscan2
- CACNA2D1 | c.1851C>G p.Y617* (on ENST00000356253 / NM_001366867.1; = p.Y598* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100667465; called by muse, mutect2, varscan2
- CDH20 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV53015770; called by muse, mutect2, varscan2
- CECR2 | c.2697G>T p.M899I (on ENST00000342247 / NM_001290047.2; = p.M716I on NM_001290046.1) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99379229; called by muse, mutect2, varscan2
- CFH | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661671, COSV62777097; called by muse, mutect2, varscan2
- CHST15 | c.1353G>C p.R451S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100655383; called by muse, mutect2, varscan2
- COPB1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.61); PolyPhen benign (0.091); catalogued as COSV99999597, COSV99999954; called by muse, mutect2, varscan2
- CTNND2 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs148824970; called by muse, mutect2, varscan2
- DNAH11 | c.5941G>A p.E1981K | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100181118; called by muse, mutect2, varscan2
- DNAH8 | c.12308C>T p.S4103L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100547311; called by muse, mutect2
- DNAJB9 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs755504350, COSV50812011; called by muse, mutect2, varscan2
- DNAJC14 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs374502377; called by muse, mutect2, varscan2
- DOT1L | c.3473A>G p.Q1158R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101288852; called by muse, mutect2, varscan2
- DST | c.6832C>T p.Q2278* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV55033444, COSV99760364; called by muse, mutect2, varscan2
- EXT2 | c.890G>A p.R297H (on ENST00000343631; = p.R330H on NM_000401.3) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.885); catalogued as rs773482624, CM163300, COSV100640701; called by muse, mutect2, varscan2
- FEZF1 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.285); catalogued as COSV100484566; called by muse, mutect2, varscan2
- FUT5 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.641); catalogued as COSV99399018; called by muse, mutect2, varscan2
- GLRA2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV99491642; called by muse, mutect2
- GRAMD4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765841447, COSV63031728; called by muse, mutect2, varscan2
- HOGA1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs1197920687, COSV100167454; called by muse, mutect2, varscan2
- IFNK | c.235A>G p.M79V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99219021; called by muse, mutect2, varscan2
- IRF4 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs756602021, COSV66704958; called by muse, mutect2, varscan2
- KCNB2 | c.1639A>G p.I547V | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.268); catalogued as COSV101579024; called by muse, mutect2, varscan2
- KMT2D | c.6017G>A p.W2006* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as COSV99986220; called by muse, mutect2, varscan2
- LAMA1 | c.8977G>T p.V2993F | Missense Mutation (SNP) | VAF 105/137 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101057882; called by muse, mutect2, varscan2
- LARP4B | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100295726; called by muse, mutect2, varscan2
- LCOR | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53714208, COSV99617228; called by muse, mutect2, varscan2
- LETM2 | c.1376C>A p.S459* (on ENST00000379957 / NM_001286819.2; = p.S364* on NM_144652.3) | Nonsense Mutation (SNP) | VAF 31/129 reads (24%) | catalogued as COSV52688124, COSV99907635; called by muse, mutect2, varscan2
- LIPI | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100753876; called by muse, mutect2, varscan2
- LMBRD2 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs183850401, COSV99682609, COSV99683288; called by muse, mutect2, varscan2
- MAGI1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV58344740; called by muse, mutect2, varscan2
- MFAP5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779463853, COSV63945085, COSV63945860; called by muse, mutect2, varscan2
- MRC1 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as rs1408486395; called by muse, mutect2, varscan2
- N4BP2 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99789328; called by muse, mutect2, varscan2
- NSUN4 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs748592571, COSV100197694; called by muse, mutect2, varscan2
- NXF1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.593); catalogued as COSV99586500; called by muse, mutect2, varscan2
- OR10A7 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs752974245, COSV100406638; called by muse, mutect2, varscan2
- OR52N1 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.533); catalogued as rs1564965323, COSV100398742; called by muse, mutect2, varscan2
- OSR1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99693864; called by muse, mutect2, varscan2
- PAPOLB | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423675104, COSV68199538; called by muse, mutect2, varscan2
- PAX3 | c.195C>A p.H65Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.839); catalogued as COSV51341010, COSV99286849; called by muse, mutect2, varscan2
- PCDHA2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV65367611; called by muse, mutect2, varscan2
- PCDHA7 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV100971885; called by muse, mutect2, varscan2
- PCDHB12 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs782641715, COSV53396312; called by muse, mutect2
- PGBD5 | c.1055C>T p.P352L (on ENST00000525115; = p.P421L on NM_001258311.2) | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100358379; called by muse, mutect2, varscan2
- PLCB1 | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV100572310; called by muse, mutect2, varscan2
- PLEKHO1 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 12/284 reads (4%) | catalogued as COSV50310260, COSV99215418; called by muse, mutect2
- PRG4 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs28698702, COSV100825834, COSV100825964; called by muse, mutect2, varscan2
- RASGRP2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as COSV99377667; called by muse, mutect2
- RCE1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547193; called by muse, mutect2, varscan2
- RHOBTB2 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as rs773780599, COSV99310648; called by muse, mutect2, varscan2
- RPL13A | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99201366; called by muse, mutect2, varscan2
- SBK2 | c.335C>G p.S112W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV100705265, COSV60014466; called by muse, mutect2, varscan2
- SEMA6D | c.2383G>T p.A795S (on ENST00000316364 / NM_153618.2; = p.A733S on NM_020858.2) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.196); catalogued as COSV100317702; called by muse, mutect2, varscan2
- SERPINC1 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100875134; called by muse, mutect2
- SH3PXD2B | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100288582; called by muse, mutect2, varscan2
- SHOX2 | c.508C>T p.R170* (on ENST00000441443 / NM_006884.3; = p.R194* on NM_003030.4) | Nonsense Mutation (SNP) | VAF 25/319 reads (8%) | catalogued as COSV67463734; called by muse, mutect2
- SLC6A3 | c.1029C>A p.Y343* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99548923; called by muse, mutect2, varscan2
- SPAM1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs770976726, COSV56141288; called by muse, mutect2, varscan2
- SSTR4 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs368872232, COSV54798287; called by muse, varscan2
- SYT5 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV62831233; called by muse, mutect2, varscan2
- TAOK2 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99665578; called by muse, mutect2, varscan2
- TBR1 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754584509, COSV101271554, COSV67417972; called by muse, mutect2, varscan2
- TICAM1 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99941305; called by muse, mutect2, varscan2
- TMTC2 | c.1573A>G p.N525D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100338916; called by muse, mutect2, varscan2
- TNKS | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs1043487769, COSV100127955; called by muse, mutect2, varscan2
- TOX | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV100813115; called by muse, mutect2, varscan2
- TRA2A | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV99767890; called by muse, mutect2, varscan2
- TTC21A | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100087717; called by muse, mutect2, varscan2
- TTLL9 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV100207326; called by muse, mutect2, varscan2
- TUBA3E | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); catalogued as rs763570372, COSV56058266, COSV56058383; called by muse, mutect2, varscan2
- UGGT2 | c.473A>T p.K158I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100942681; called by muse, mutect2, varscan2
- UGT3A2 | c.739T>C p.W247R | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99236894; called by muse, mutect2, varscan2
- WEE2 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs748896412, COSV101285278; called by muse, mutect2, varscan2
- ZC2HC1A | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV99804496; called by muse, mutect2, varscan2
- ZNF484 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs750907980, COSV60258532; called by muse, mutect2, varscan2
- ZNF713 | c.952C>T p.Q318* (on ENST00000633730 / NM_001366796.2; = p.Q331* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 41/196 reads (21%) | catalogued as COSV101448757; called by muse, mutect2, varscan2
- ZNF800 | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as COSV99758235; called by muse, mutect2, varscan2
- DIP2B | c.2048+3_2048+7del p.X683_splice | Splice Site (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel*
- EFL1 | c.1817_1821del p.P606Hfs*16 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- FCGBP | c.7850G>A p.G2617D | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- HRNR | c.5473G>A p.G1825R | Missense Mutation (SNP) | VAF 34/1368 reads (2%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2
- KCNH3 | c.2576-4_2576del p.X859_splice | Splice Site (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- MN1 | c.114_126del p.F39Gfs*10 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- MYH9 | c.2435_2437del p.L812del | In Frame Del (DEL) | VAF 26/72 reads (36%) | called by pindel, varscan2
- POLA2 | c.1653_1668del p.L552* | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- SEC16A | c.4129-28_4136del p.X1377_splice | Splice Site (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel
- SNAPC1 | c.205_207del p.P69del | In Frame Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3152C>T p.S1051F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SS18 | c.659dup p.G221Rfs*19 | Frame Shift Ins (INS) | VAF 65/131 reads (50%) | called by mutect2, pindel, varscan2
- TP53 | c.351del p.T118Qfs*5 | Frame Shift Del (DEL) | VAF 44/84 reads (52%) | called by mutect2, pindel, varscan2
- ARMH4 | c.2154A>C p.V718= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as COSV99959090; called by muse, mutect2, varscan2
- ASB9 | c.372C>T p.H124= | Silent (SNP) | VAF 49/63 reads (78%) | catalogued as rs752881555, COSV100995595; called by muse, mutect2, varscan2
- ATP9A | c.2367C>T p.D789= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs377730874; called by muse, mutect2, varscan2
- AVPR1B | c.520C>T p.L174= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV100899468; called by muse, mutect2, varscan2
- CCT6A | c.162C>T p.I54= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as rs1368450875, COSV99303793; called by muse, mutect2, varscan2
- CDK11B | c.141C>A p.S47= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV100478298; called by muse, mutect2, varscan2
- CLSTN3 | c.2094G>T p.S698= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV99867778; called by muse, mutect2, varscan2
- DNAH5 | c.6012C>T p.F2004= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as rs1561375651, COSV54263479; called by muse, mutect2, varscan2
- ELN | c.2040C>T p.L680= (on ENST00000320399 / NM_001278939.1; = p.L647= on NM_000501.4) | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as rs782117709, COSV99332585; called by muse, mutect2, varscan2
- EPHX4 | c.27C>G p.P9= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100952784; called by muse, mutect2, varscan2
- F11 | c.1146C>T p.T382= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV99250942; called by muse, mutect2, varscan2
- F13A1 | c.430C>A p.R144= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs767046666, COSV53553269, COSV99344063; called by muse, mutect2, varscan2
- FAM104A | c.282T>C p.S94= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV101303963; called by muse, mutect2, varscan2
- GIMAP8 | c.1872G>T p.L624= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV100217725; called by muse, mutect2, varscan2
- GPC5 | c.1047A>T p.V349= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV100996083; called by muse, mutect2
- IL2 | c.33A>G p.A11= | Silent (SNP) | VAF 43/69 reads (62%) | catalogued as COSV99900850; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1410C>T p.P470= (on ENST00000485419 / NM_001197113.1; = p.P394= on NM_014575.3) | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs748065484, COSV100542313; called by muse, mutect2, varscan2
- KIAA1522 | c.594C>T p.P198= (on ENST00000373480 / NM_001198972.2; = p.P257= on NM_020888.3) | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1470023280, COSV99615186; called by muse, mutect2, varscan2
- LRRIQ4 | c.798G>A p.G266= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as COSV100540116, COSV61619895; called by muse, mutect2
- LZTR1 | c.1833G>A p.V611= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as rs770260964, COSV99302356; called by muse, mutect2, varscan2
- NEMP1 | c.993G>A p.K331= (on ENST00000300128 / NM_001130963.2; = p.K258= on NM_015257.3) | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV100272344; called by muse, mutect2, varscan2
- NOTCH2 | c.4494G>A p.G1498= | Silent (SNP) | VAF 34/595 reads (6%) | catalogued as rs947914834, COSV99867023; called by muse, mutect2
- OR13A1 | c.66T>C p.S22= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100981100; called by muse, mutect2, varscan2
- PCDHB1 | c.828G>T p.A276= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100128435, COSV60629538; called by muse, mutect2, varscan2
- PCDHB7 | c.1986G>T p.L662= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99177475; called by muse, mutect2, varscan2
- PLEKHH2 | c.1146C>T p.S382= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV99175157; called by muse, mutect2, varscan2
- PXDNL | c.2958C>T p.S986= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs952661664, COSV62477568; called by mutect2, varscan2
- RSPH10B | c.1755G>A p.L585= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as rs764412837, COSV61756280; called by muse, mutect2, varscan2
- RUSC1 | c.912C>T p.S304= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV99430329; called by muse, mutect2, varscan2
- SEPTIN3 | c.369C>T p.V123= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs751374313, COSV99352416; called by muse, mutect2, varscan2
- TIMELESS | c.2835G>A p.K945= | Silent (SNP) | VAF 83/155 reads (54%) | catalogued as rs113553695, COSV99974378; called by muse, mutect2, varscan2
- TRPM3 | c.4578C>T p.S1526= (on ENST00000357533 / NM_001366142.2; = p.S1381= on NM_020952.6) | Silent (SNP) | VAF 61/92 reads (66%) | catalogued as rs1159983006, COSV62580133; called by muse, mutect2, varscan2
- TTN | c.52020G>A p.A17340= (on ENST00000591111; = p.A9916= on NM_003319.4) | Silent (SNP) | VAF 63/243 reads (26%) | catalogued as rs370998052; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZDHHC23 | c.445C>T p.L149= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV100362265, COSV57629391; called by muse, mutect2, varscan2
- TTN | c.34523-144C>T | Intron (SNP) | VAF 103/262 reads (39%) | catalogued as COSV100632427; called by muse, mutect2, varscan2
